Gene-level copy-number profile of specimen HCM-CSHL-0158-C20-85A from HCMI case HCM-CSHL-0158-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 57.2 years (20,877 days).
Specimen HCM-CSHL-0158-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 11c24737-35a0-4ca5-8865-4ed9d6237f1d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0158-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/1e4eda39-50e7-42d7-bbf3-1b943f8eeb03

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,091; copy number 2: 6,540; copy number 3: 20,491; copy number 4: 24,167; copy number 5: 831; copy number 6: 3,083; copy number 7: 1,299; copy number 8: 180; copy number 9: 1,113; copy number 10: 108; copy number 11: 7; copy number 12: 2; copy number 13: 1; copy number 14: 2; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,234 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–48,385,049, 46 genes, copy number 9: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19.
- chr8:49,086,301–49,512,180, 4 genes, copy number 9: AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2.
- chr8:49,740,216–50,796,692, 4 genes, copy number 9 (within-gene range 8–9): PSAT1P1, AC113145.1, AC023762.1, SNTG1.
- chr8:50,490,795–53,484,067, 31 genes, copy number 9: AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1, AC131902.1, AC022034.3, AC131902.2.
- chr8:53,532,908–54,871,720, 27 genes, copy number 9: AC022034.2, MAPK6P1, AC103778.1, ATP6V1H, RGS20, AC113194.1, RPS27AP13, RNU6-1331P, TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1.
- chr8:55,696,424–56,588,787, 27 genes, copy number 9–10: TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6.
- chr8:56,917,084–57,984,126, 15 genes, copy number 9: RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1.
- chr8:58,255,771–61,714,640, 41 genes, copy number 9 (within-gene range 8–9): AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH.
- chr8:61,631,680–64,798,737, 43 genes, copy number 9–10: RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2.
- chr8:64,973,488–68,819,023, 58 genes, copy number 9–10 (within-gene range 8–10): AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34.
- chr8:68,695,643–68,852,763, 2 genes, copy number 9–10: RNA5SP269, AC083967.1.
- chr8:69,424,849–72,938,349, 49 genes, copy number 9–10 (within-gene range 8–10): LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2, AC009446.1, AC104012.1, U8, MSC-AS1, MSC, RPS20P20, TRPA1, AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2.
- chr8:72,874,859–73,370,601, 16 genes, copy number 9: AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2.
- chr8:73,420,369–76,683,308, 50 genes, copy number 9–10 (within-gene range 8–10): STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G, AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1.
- chr8:77,013,751–88,887,573, 160 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr8:88,485,110–91,219,236, 31 genes, copy number 9–10 (within-gene range 8–10): AC090568.1, AC090578.2, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2, RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661.
- chr8:91,542,924–96,069,681, 87 genes, copy number 9–10 (broad region; genes not listed).
- chr8:96,222,947–96,261,610, 3 genes, copy number 9: UQCRB, AP003465.1, MTERF3.
- chr8:96,370,800–96,431,160, 2 genes, copy number 9: AP003548.1, RNU6-1172P.
- chr8:97,241,742–99,877,580, 39 genes, copy number 9–10 (within-gene range 8–10): AP003115.1, TSPYL5, SNORD3H, AP002982.1, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B.
- chr8:99,119,352–101,262,903, 55 genes, copy number 9–10: AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844.
- chr8:101,307,367–106,060,524, 82 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr8:105,737,280–127,482,139, 239 genes, copy number 9–10 (broad region; genes not listed).
- chr8:127,686,343–129,683,770, 19 genes, copy number 9–10 (within-gene range 8–10): CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206.
- chr8:129,484,057–133,302,022, 45 genes, copy number 9: MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1, ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1.
- chr8:133,886,496–133,902,407, 1 gene, copy number 9: AC110741.1.
- chr8:134,477,788–134,979,279, 16 genes, copy number 9: ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56.
- chr8:135,859,369–137,092,183, 1 gene, copy number 9 (within-gene range 8–9): LINC02055.
- chr8:137,424,904–137,698,467, 2 genes, copy number 9: ZYXP1, AC110053.1.
- chr8:138,130,023–138,914,041, 2 genes, copy number 9: FAM135B, COL22A1.
- chr8:140,505,813–141,002,216, 10 genes, copy number 9: AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr8:144,698,614–144,902,168, 12 genes, copy number 9: AF186192.1, AF186192.2, AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, ZNF250.
- chr20:57,599,695–58,515,399, 15 genes, copy number 10–19 (within-gene range 6–19): AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L.

Autosomal genes at a single copy (total copy number 1): 579. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
